Somatic mutation profile of tumor specimen TCGA-AB-2942-03A (aliquot TCGA-AB-2942-03A-01W-0733-08) from TCGA case TCGA-AB-2942, project TCGA-LAML (Acute Myeloid Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute myelomonocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 67.8 years (24,776 days).
Specimen TCGA-AB-2942-03A: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 08d2701c-5e73-47ab-8e31-808efa7e2736.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AB-2942-11A (Solid Tissue Normal), aliquot TCGA-AB-2942-11A-01W-0732-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bce8cf19-cf9a-468e-8899-f2b360c541ca

The open-access MAF lists 2 somatic variants for this specimen: 2 protein-altering or splice-affecting.
By variant classification: Missense Mutation 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CELSR1 | c.8032G>A p.D2678N | Missense Mutation (SNP) | VAF 13/24 reads (54%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.721); catalogued as rs750773769, COSV99416655; called by muse, varscan2
- MYH7B | c.4174C>T p.R1392W | Missense Mutation (SNP) | VAF 3/48 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1444587955; called by muse, mutect2
